Surgical pathology report (de-identified scan), TCGA case TCGA-GC-A3WC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-GC-A3WC-01A (Primary Tumor).

[page 1 of 2]
Sex:
D.O.B.:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

DIAGNOSIS:

A. Right ureter, excision:

Complete cross section of benign ureter, no tumor identified.
Intraoperative consultation corroborated.

B. Left ureter, excision:

Complete cross section of benign ureter, no tumor identified.
Intraoperative consultation corroborated.

C. Bladder, pelvic lymph nodes; cystectomy:

Tumor Characteristics:

1. Histologic type: Urothelial carcinoma.
2. Histologic grade: Poorly-differentiated.
3. Tumor size: 5.3 x 2.2 x 0.5 cm.
4. Microscopic tumor extension: Tumor invades completely through the muscularis propria into the surrounding adipose tissue.
5. Lymphovascular space invasion: Present.

Surgical Margins:

1. Surgical margins including left and right ureter, urethra, and deep soft tissue are negative for tumor.

Lymph Node Status:

1. Total number of lymph nodes examined: 2
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/2).

Other:

1. Focal urothelial dysplasia present.
2. pTNM stage: pT3, N0.

evaluated by:	[Signature] 12/25/12	

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: None given

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

ICD-O-3

Carcinoma, urothelial, NOS

8120/3

Site: bladder, NOS

C67.9

5-1-12 ED

SPECIMENS:

- A. Right ureter with frozen section
- B. Left ureter with frozen section
- C. Bladder and pelvic lymph nodes

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three containers labeled with the patient's name.

Container A is additionally labeled "right ureter" and contains a 0.4 cm in length by 0.4 cm diameter cylindrical portion of pink-tan soft tissue consistent with ureter. The specimen is entirely submitted for frozen section. The residual wrapped in tissue paper and entirely resubmitted for permanent section in cassette A labeled.

Container B is additionally labeled "left ureter, clip on distal end" and contains a 0.4 cm in length by 0.4 cm diameter, pink-tan cylindrical soft tissue with adherent fibroadipose tissue. A clip is present at one end and denotes distal. The specimen is entirely submitted for frozen section with the residual wrapped in tissue paper and entirely resubmitted for permanent section in cassette B labeled.

[page 2 of 2]
Container C is additionally labeled "Bladder and pelvic lymph nodes" and contains a cystectomy specimen having overall dimensions of 10.0 x 7.0 x 4.5 cm. The specimen is comprised of bladder (6.0 x 6.0 x 4.0 cm), right ureter (4.5 cm in length by 0.3 cm in diameter), left ureter (5.5 cm in length by 0.3 cm), associated pericystic fat, and portion of vaginal mucosa (6.0 x 3.0 cm). The vaginal mucosa is purple-pink, glistening and erythematous with no discrete lesions. The urethral margin is inked, amputated and radially sectioned to reveal a 5.3 x 2.2 x 0.5 cm, pink-tan, fungating, friable and ulcerated mass involving the right lateral wall. This mass approaches to within 4.0 cm of the urethral margin and to within 0.6 cm of the right ureteral orifice. Additionally, this mass resides 2.5 cm from the left ureteral orifice. On section, this mass invades 1.8 cm through the detrusor muscle and approaching to within 0.2 cm of the inked deep margin. The remainder of the mucosa is pink-tan and glistening with no additional lesions. On section and palpation, no lymph nodes are identified within the perivesicular fat.

Also received in the same container is a 4.5 x 3.0 x 1.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, two firm fatty possible lymph nodes are identified, 1.0 and 2.0 cm in greatest dimension. Representative sections are submitted in cassettes C1-14 labeled designated as follows: C1-2 urethral margin, perpendicular; C3 mass to inked deep margin and right ureteral orifice; 4-6 mass to inked deep margin; 7 mass to normal appearing mucosa; 8 trigone to include vaginal mucosa; 9 posterior bladder wall; 10 bladder dome; 11 anterior bladder wall; 12 left ureteral orifice; 13 one whole possible lymph node; 14 one whole possible bisected lymph node. Additionally, a yellow, green and blue cassette are submitted for genomics research, each labeled

POST-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS: FSA: Negative per
results were communicated to after confirming patient identity.

FROZEN SECTION DIAGNOSIS: FSB: Negative per Dr.

Source: NCI Genomic Data Commons file ee6fb6fe-15ef-4f32-8954-4c43799eca78 (TCGA-GC-A3WC.91347009-C0A1-4BB1-8445-D00B769B59AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).